Somatic mutation profile of tumor specimen TARGET-20-PARHJA-09A (aliquot TARGET-20-PARHJA-09A-01D) from TARGET case TARGET-20-PARHJA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.8 years (6,132 days).
Specimen TARGET-20-PARHJA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a624f9b1-9f15-4980-8eef-86dd6154e51f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARHJA-14A (Bone Marrow Normal), aliquot TARGET-20-PARHJA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa0a791c-0266-436d-85f9-a226bc1fba3c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>A p.T58N (on ENST00000377970; = p.T73N on NM_002467.6) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52367994, COSV52373588; called by muse, mutect2, varscan2
- CACNA1B | c.5461T>C p.L1821= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1252942983; called by muse, mutect2, varscan2
